Somatic mutation profile of tumor specimen TCGA-DB-A75M-01A (aliquot TCGA-DB-A75M-01A-11D-A32B-08) from TCGA case TCGA-DB-A75M, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.3 years (17,289 days).
Specimen TCGA-DB-A75M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 461e7189-9eda-4ae3-9c44-9368a19c256b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A75M-10A (Blood Derived Normal), aliquot TCGA-DB-A75M-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2248d05-23d1-4e5f-9981-4240ac9e50a4

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 20, Silent 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 22/25 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs778986887, COSV99347067; called by muse, mutect2, varscan2
- AGMO | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100693825; called by muse, mutect2, varscan2
- ANKRD50 | c.4240A>G p.I1414V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as COSV101538910; called by muse, mutect2, varscan2
- ARID2 | c.4277C>A p.S1426* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV100535676; called by muse, mutect2
- ATP7A | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs377714939, COSV58445652; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATR | c.4382+2T>C p.X1461_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100637838; called by muse, mutect2, varscan2
- DNAH7 | c.7853T>C p.V2618A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV100414374; called by muse, mutect2
- INTU | c.1481A>G p.E494G | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080572; called by muse, mutect2, varscan2
- IRF4 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101110794; called by muse, mutect2, varscan2
- KAT7 | c.827G>A p.S276N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs753668478, COSV99371654; called by muse, varscan2
- MATN2 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs199853259, COSV54706874, COSV99647089; called by muse, mutect2, varscan2
- NOBOX | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99779281; called by muse, varscan2
- PROCR | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV99405709; called by mutect2, varscan2
- PRSS12 | c.1852G>C p.V618L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.139); catalogued as rs145983533; called by muse, mutect2, varscan2
- RUNX3 | c.1054G>T p.G352W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136726; called by muse, mutect2, varscan2
- SCAI | c.832G>A p.A278T (on ENST00000336505 / NM_001144877.3; = p.A301T on NM_173690.5) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs369558159; called by muse, mutect2, varscan2
- SDR16C5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV58128033; called by muse, mutect2
- SF3B1 | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100134079, COSV100135191; called by muse, mutect2, varscan2
- STAR | c.598G>C p.A200P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1333130388, COSV99378958; called by muse, mutect2, varscan2
- TCEAL1 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101010103; called by muse, mutect2, varscan2
- ATRX | c.1096del p.M366* | Frame Shift Del (DEL) | VAF 51/81 reads (63%) | called by mutect2, pindel, varscan2
- SETD3 | c.1509A>G p.E503= | Silent (SNP) | VAF 13/207 reads (6%) | catalogued as COSV100074916; called by muse, mutect2
- SLC12A3 | c.1050G>A p.S350= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs752171513, COSV52633423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
